MMRF case MMRF_1835 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/67ba43b8-1bd5-4cf0-bea9-f8a624e85a7b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.5 years (24,304 days); ISS stage: II; Days to last known disease status: 1,103 days (3.0 years); Days to last follow up: 1,103 days (3.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 9 days; Days to treatment end: 282 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 282 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 305 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 372 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 373 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 74.5 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 30 g/L; Total Protein 10.9 g/dL; Glucose 4.73 mmol/L.
- Day 92 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 5.72 mmol/L.
- Day 183 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 9.5 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 5.39 mmol/L.
- Day 267 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 5.17 mmol/L.
- Day 373 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 5.4 g/dL; Glucose 4.95 mmol/L.
- Day 457: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 4.73 mmol/L.
- Day 540 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.91 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 4.62 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 6.87 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5.2 g/dL; Glucose 4.95 mmol/L.
- Day 737 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 5.7 g/dL; Glucose 5.34 mmol/L.
- Day 821 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 8.52 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.68 mmol/L.
- Day 906 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 8.83 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 6.02 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 997 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 3.8 mmol/L.
- Day 1,103 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -17: Weight: 77 kg; Height: 173 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1835_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1835_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
